Somatic mutation profile of tumor specimen TARGET-10-PARPGJ-09A (aliquot TARGET-10-PARPGJ-09A-01D) from TARGET case TARGET-10-PARPGJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,131 days).
Specimen TARGET-10-PARPGJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4a8b60-961f-4db0-8e62-931ced53fad3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPGJ-10A (Blood Derived Normal), aliquot TARGET-10-PARPGJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2be0be9-cfc1-4f85-85d8-ccc724b1351a

The open-access MAF lists 76 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Intron 11, 3'UTR 3, RNA 2, 5'Flank 2, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55869027; called by muse, mutect2, varscan2
- ADGRL4 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.958); catalogued as COSV100875716; called by muse, mutect2, varscan2
- CTAG2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.013); catalogued as rs782192001; called by muse, mutect2, varscan2
- ESR1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.937); catalogued as COSV99237523; called by muse, mutect2, varscan2
- FAM131A | c.956C>T p.S319F (on ENST00000310585; = p.S350F on NM_144635.5) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406341926; called by muse, mutect2, varscan2
- ITGB5 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs375058260, COSV56151236; called by muse, mutect2, varscan2
- KHDRBS2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258889534, COSV99832027; called by muse, mutect2, varscan2
- LIPI | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV60713210; called by muse, mutect2, varscan2
- MMP12 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1555009615; called by muse, mutect2, varscan2
- NDST3 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV99631354; called by muse, mutect2, varscan2
- NXNL2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as rs1347435269, COSV65474401; called by muse, mutect2
- PDGFRA | c.1037G>T p.R346M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as rs78608730; called by muse, mutect2, varscan2
- PLEC | c.8552C>T p.A2851V (on ENST00000322810 / NM_201380.4; = p.A2741V on NM_000445.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1411552060; called by muse, mutect2, varscan2
- RAB34 | c.150T>G p.F50L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1181062242; called by muse, mutect2
- RADIL | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs758019619, COSV68200336; called by muse, mutect2, varscan2
- RNPC3 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as rs1177375172; called by muse, mutect2, varscan2
- SLC25A23 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs755807545; called by muse, mutect2, varscan2
- TLN2 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.419); catalogued as rs1454548338; called by muse, mutect2, varscan2
- TTN | c.26963G>A p.R8988Q (on ENST00000591111; = p.R8061Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/119 reads (43%) | PolyPhen benign (0.376); catalogued as rs397517527; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR81 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs370613522; called by muse, mutect2, varscan2
- ZNF469 | c.10664C>T p.S3555F (on ENST00000437464; = p.S3583F on NM_001367624.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs767728536, COSV71258333; called by muse, mutect2, varscan2
- ZNF548 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253755849, COSV60240969; called by muse, mutect2, varscan2
- CCDC183 | c.1161G>C p.E387D | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.8255G>A p.R2752K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL28A1 | c.267T>G p.Y89* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- DNAH2 | c.11661G>A p.Q3887= | Splice Region (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- EBF2 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD4 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HIVEP1 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ITGAV | c.3095A>T p.E1032V | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAK1 | c.1885A>T p.R629W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ4 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYCL | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NUP153 | c.3746C>T p.S1249F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PPP3CC | c.1097_1098insG p.N366Kfs*5 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- PROSER2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TMEM245 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC6A | c.428C>T p.S143F (on ENST00000585934 / NM_001270891.2; = p.S157F on NM_024108.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TYRP1 | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- USPL1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF521 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ANKH | c.219C>T p.G73= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99414669; called by muse, mutect2, varscan2
- BOC | c.729C>T p.T243= | Silent (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- CACNA1D | c.4899G>A p.A1633= (on ENST00000350061 / NM_001128840.3; = p.A1653= on NM_000720.4) | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs752608965; called by muse, mutect2, varscan2
- CNTNAP2 | c.3561C>T p.I1187= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs775209615, COSV62192752, COSV62265806; called by muse, mutect2, varscan2
- CYP1A2 | c.594C>T p.N198= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as rs567343028; called by muse, mutect2, varscan2
- FEZF1 | c.252G>A p.T84= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1044842458, COSV58659651; called by muse, mutect2, varscan2
- FGD4 | c.1185G>A p.R395= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- GNAT1 | c.414C>T p.R138= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs544821663, COSV50029238; called by muse, mutect2
- HS6ST3 | c.1209G>A p.L403= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- JPH1 | c.768G>A p.T256= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as COSV60614037; called by muse, mutect2, varscan2
- NUP210 | c.1692C>T p.P564= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs368549966; called by muse, mutect2, varscan2
- SI | c.1680C>T p.S560= | Silent (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- TSPAN10 | c.834C>T p.P278= (on ENST00000574882 / NM_001290212.1; = p.P240= on NM_031945.4) | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- TYRP1 | c.1542C>T p.L514= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as rs751553879; called by muse, mutect2, varscan2
- XK | c.930G>A p.K310= | Silent (SNP) | VAF 85/90 reads (94%) | called by muse, mutect2, varscan2
- AC034198.1 | n.65G>A | RNA (SNP) | VAF 28/65 reads (43%) | catalogued as rs918645645; called by muse, mutect2, varscan2
- BID | c.362-81C>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- C2orf73 | c.*42G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- DCAF4L1 | c.*65C>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | catalogued as rs780788596; called by muse, mutect2
- FMN1 | c.3929-6679G>A | Intron (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- HOXD1 | c.*18G>A | 3'UTR (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100514058; called by muse, mutect2, varscan2
- IL13 | c.175-118C>T | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs1223391598; called by muse, mutect2
- IYD | c.687+1179C>T | Intron (SNP) | VAF 39/80 reads (49%) | catalogued as rs375895425; called by muse, mutect2, varscan2
- MIR2052 | chr8:74703681 G>A | 5'Flank (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- MIRLET7F1 | chr9:94175895 C>T | 5'Flank (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- MRPS9 | c.930-22A>G | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- NBPF22P | n.646C>T | RNA (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+2772C>T | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- SH3TC2 | c.280-1376G>A | Intron (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25091908 G>A | 3'Flank (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- STXBP2 | c.429+53C>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2775C>T | Intron (SNP) | VAF 42/95 reads (44%) | catalogued as rs760470600; called by muse, mutect2, varscan2
- TSPAN32 | c.181+501G>A | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2
- UAP1L1 | c.495-64C>T | Intron (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100814505; called by muse, mutect2, varscan2
